Somatic mutation profile of tumor specimen MMRF_2419_2_BM_CD138pos (aliquot MMRF_2419_2_BM_CD138pos_T1_KHS5U_L12908) from MMRF case MMRF_2419, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.4 years (20,236 days).
Specimen MMRF_2419_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 390d0055-4f29-46c3-8d42-c3d24211cffa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2419_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2419_1_PB_Whole_C3_KHS5U_L11253; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13dba014-5e89-4726-8427-54a311752509

The open-access MAF lists 89 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 25, Intron 13, Silent 10, RNA 3, Splice Site 2, 5'UTR 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 78/192 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.2688G>A p.M896I (on ENST00000506720 / NM_001322402.2; = p.M828I on NM_015236.6) | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV72230594; called by muse, mutect2, varscan2
- ALDH1A2 | c.110A>C p.Y37S | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV99990720; called by muse, mutect2, varscan2
- ANKK1 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1221272474; called by muse, mutect2, varscan2
- ARL6IP4 | c.1177G>A p.V393I (on ENST00000315580 / NM_018694.3; = p.V374I on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as rs137934270; called by muse, mutect2, varscan2
- FAM83C | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777921694, COSV65584721; called by muse, mutect2, varscan2
- FARSB | c.58+2T>A p.X20_splice | Splice Site (SNP) | VAF 10/136 reads (7%) | catalogued as rs1310042249; called by muse, mutect2
- HIRA | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs193106800, COSV54272308; called by muse, mutect2, varscan2
- NEGR1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs373419972; called by muse, mutect2, varscan2
- NET1 | c.1081G>A p.E361K (on ENST00000355029 / NM_001047160.3; = p.E307K on NM_005863.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs773238555, COSV61790669; called by muse, mutect2, varscan2
- PRR12 | c.413C>T p.A138V (on ENST00000615927; = p.A959V on NM_020719.3) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs371098369; called by muse, mutect2, varscan2
- PSMG2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs753428683; called by muse, mutect2, varscan2
- RBMXL3 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.092); catalogued as rs1320429834; called by muse, mutect2
- SART1 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs142409678; called by muse, mutect2, varscan2
- SLC18A3 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1242707628, COSV60322729; called by muse, mutect2
- SLC4A8 | c.1104T>A p.I368= | Splice Region (SNP) | VAF 134/287 reads (47%) | catalogued as COSV60656291; called by muse, mutect2, varscan2
- SYT8 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as rs1412100455, COSV53290297; called by muse, mutect2, varscan2
- UBR5 | c.6878G>A p.R2293Q | Missense Mutation (SNP) | VAF 114/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55300395; called by muse, mutect2, varscan2
- ART5 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CA10 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CAPN6 | c.1199T>G p.M400R | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2
- CEP162 | c.3383A>G p.E1128G | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CEP290 | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FASTKD2 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 99/174 reads (57%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR149 | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IGHV1-69D | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 100/132 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, varscan2
- IGHV2-70 | c.240_244delinsTACCC p.S81_T82delinsTP | Missense Mutation (ONP) | VAF 12/79 reads (15%) | called by muse*, pindel
- IGHV5-51 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, varscan2
- IGLV3-1 | c.156del p.W53Gfs*39 | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | called by pindel, varscan2
- LIN7B | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- OTUD1 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAP1GAP2 | c.1981-2A>G p.X661_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SASS6 | c.1516A>G p.R506G | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SLIT2 | c.1134A>T p.L378F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SULT1C3 | c.572C>A p.A191E | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ZNF813 | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CCDC166 | c.570C>T p.F190= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV72638779; called by muse, mutect2, varscan2
- CCDC6 | c.1065T>C p.P355= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- CHRM3 | c.684G>A p.E228= | Silent (SNP) | VAF 98/161 reads (61%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.969C>T p.N323= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs370189631, COSV60481200; called by muse, mutect2, varscan2
- GEMIN4 | c.144G>A p.E48= | Silent (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- IGLL5 | c.195C>T p.S65= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs151173231, COSV104440338, COSV73251128; called by muse, mutect2, varscan2
- MATN1 | c.9C>T p.V3= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs1003337998; called by muse, mutect2, varscan2
- NPAP1 | c.2031C>T p.D677= | Silent (SNP) | VAF 82/359 reads (23%) | called by muse, mutect2, varscan2
- NR0B2 | c.684G>A p.P228= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs779899657; called by muse, mutect2
- SEPTIN9 | c.390C>T p.F130= (on ENST00000427177 / NM_001113491.2; = p.F112= on NM_006640.4) | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as rs769409038; called by mutect2, varscan2
- AC112198.1 | n.1127G>A | RNA (SNP) | VAF 38/366 reads (10%) | called by muse, mutect2
- ACO1 | c.*82T>G | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2
- BLCAP | c.-176-1980G>A | Intron (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
- BMPR1A | c.*544C>T | 3'UTR (SNP) | VAF 9/221 reads (4%) | catalogued as rs1440506479; called by muse, mutect2
- C22orf42 | c.493+16del | Intron (DEL) | VAF 28/74 reads (38%) | catalogued as rs745800176, COSV66075696; called by mutect2, varscan2
- CIZ1 | c.2487+137G>C | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- CLCN3 | c.*379_*381del | 3'UTR (DEL) | VAF 34/83 reads (41%) | called by mutect2, pindel, varscan2
- COL9A1 | c.781-209T>C | Intron (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- CXCL14 | c.*732T>C | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.*1168G>A | 3'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- FAM90A27P | n.833C>A | RNA (SNP) | VAF 61/214 reads (29%) | catalogued as rs1363215788; called by muse, mutect2, varscan2
- FGFBP3 | c.*638T>G | 3'UTR (SNP) | VAF 18/20 reads (90%) | called by muse, varscan2
- FOXQ1 | c.*332A>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- FRA10AC1 | c.826+2859G>C | Intron (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- GIN1 | c.*538A>G | 3'UTR (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- HGF | c.482+133G>T | Intron (SNP) | VAF 19/91 reads (21%) | catalogued as rs573900535; called by muse, mutect2, varscan2
- IGF1R | c.*3700G>A | 3'UTR (SNP) | VAF 76/218 reads (35%) | called by muse, mutect2, varscan2
- KMT2A | chr11:118524790 C>A | 3'Flank (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- LY6G5C | c.*100_*106dup | 3'UTR (INS) | VAF 13/52 reads (25%) | called by mutect2, varscan2
- MIR5195 | n.30G>A | RNA (SNP) | VAF 41/84 reads (49%) | catalogued as rs1321858136; called by muse, mutect2, varscan2
- MMP24 | c.*1373G>A | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- NOSTRIN | c.*133A>T | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- PARP11 | c.*862T>A | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- PCDH10 | c.*341A>T | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- PCDH11Y | c.3129+4105G>T | Intron (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4743G>A | Intron (SNP) | VAF 7/175 reads (4%) | catalogued as COSV56478339; called by muse, mutect2
- PDE10A | c.*1238T>G | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- PPM1F | c.*898T>C | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- PSAT1 | c.-67del | 5'UTR (DEL) | VAF 43/192 reads (22%) | called by mutect2, pindel, varscan2
- RIPPLY3 | c.*821del | 3'UTR (DEL) | VAF 48/121 reads (40%) | catalogued as rs1299285804; called by mutect2, pindel, varscan2
- RNF11 | c.*772T>C | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- SMARCC1 | c.*2620_*2621del | 3'UTR (DEL) | VAF 35/218 reads (16%) | called by mutect2, pindel, varscan2
- SP110 | c.1590+1018G>A | Intron (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*1634A>G | 3'UTR (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- TMEM167A | c.*246T>C | 3'UTR (SNP) | VAF 43/180 reads (24%) | called by muse, mutect2, varscan2
- TMEM68 | c.325+1695T>G | Intron (SNP) | VAF 45/46 reads (98%) | called by muse, mutect2, varscan2
- TMTC1 | c.*1153A>G | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- TTC39A | c.1253+249A>C | Intron (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- TTC39A | c.1162-2405G>A | Intron (SNP) | VAF 72/151 reads (48%) | catalogued as rs1024252983; called by muse, mutect2, varscan2
- XKR4 | c.*1700G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | catalogued as COSV59304750; called by muse, mutect2, varscan2
- XPOT | c.*2202G>A | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- ZFAND3 | c.*2003G>T | 3'UTR (SNP) | VAF 46/75 reads (61%) | called by muse, mutect2, varscan2
- ZNF300 | c.265+515C>T | Intron (SNP) | VAF 54/152 reads (36%) | called by muse, mutect2, varscan2
